Gene-level copy-number profile of tumor specimen TCGA-MP-A4TA-01A from TCGA case TCGA-MP-A4TA, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 75.3 years (27,513 days).
Specimen TCGA-MP-A4TA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.08620aad-0299-477a-ab8f-3339f5f45d60.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 3,991 have no estimate.
https://portal.gdc.cancer.gov/files/186d4bf0-836c-4cd7-968c-0eadee69d709

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 23,417; copy number 2: 31,609; copy number 3: 998; copy number 4: 329; copy number 5: 268; copy number 7: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-MP-A4TA-01A-21D-A24O-01): tumor purity 0.33, ploidy 1.65, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:97,737,894–97,738,913, 1 gene: AC112203.1.
- chr12:7,812,512–7,976,360, 9 genes (within-gene range 0–2): SLC2A14, Metazoa_SRP, AC006517.1, AC124891.1, NANOGP1, AC007536.1, SLC2A3, AC006511.6, Y_RNA.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 269 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:32,689,070–32,888,145, 2 genes, copy number 5–7: NPR3, AC025459.1.
- chr5:32,947,443–32,962,467, 1 gene, copy number 5: LINC02120.
- chr8:35,862,123–42,555,195, 149 genes, copy number 5 (broad region; genes not listed).
- chr15:19,955,300–21,653,276, 85 genes, copy number 5 (broad region; genes not listed).
- chr15:21,843,750–22,373,570, 29 genes, copy number 5: MIR3118-4, POTEB, RNU6-631P, ZNF519P3, NF1P2, MIR5701-3, OR11J7P, OR11J6P, AC134980.1, OR11H3P, AC134980.2, OR11K1P, OR4Q1P, OR4H6P, OR4M2, OR4N4, OR4N3P, AC010760.1, RPS8P10, IGHV1OR15-1, IGHV1OR15-3, IGHV4OR15-8, IGHV1OR15-4, AC025884.3, MIR1268A, AC025884.2, AC025884.1, AC100757.2, AC100757.1.
- chr16:14,974,591–15,139,339, 3 genes, copy number 5: PDXDC1, NTAN1, RRN3.

Autosomal genes at a single copy (total copy number 1): 23,417. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
